Surgical pathology report (de-identified scan), TCGA case TCGA-MN-A4N5, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site BLN - Baylor, specimen TCGA-MN-A4N5-01A (Primary Tumor).

[page 1 of 4]
PATHOLOGY REPORT

GROSS DESCRIPTION:

A. The specimen consists of a 193 gm, 18.2 x 11.5 x 2.5 cm lobe of lung displaying a 5.5 cm in length linear staple line superior to the bronchus. The bronchial resection margin is removed en face and submitted for frozen section diagnosis and subsequent routine histology in cassette FSA. The remaining pleural surface is tan-pink and smooth with a 1.0 x 1.0 cm area of induration and puckering along the lateral aspect. The area of pleural puckering is inked blue. The linear staple line is removed, and the underlying parenchyma is inked black.

Sectioning reveals a 1.6 x 1.6 x 0.8 cm, tan-yellow to white, granular, poorly demarcated mass underlying the aforementioned area of pleural puckering and induration. The mass approaches the pleural surface. The mass is 4.3 cm from the bronchial resection margin, and 3.6 cm from the closest vascular resection margin. The mass is 4.6 cm from the closest staple line surface.

The remaining lung parenchyma is tan-pink to red and unremarkable. No areas of congestion, consolidation, or emphysematous change are grossly appreciated. Sectioning through the peribronchial region reveals multiple dark black, rubbery, anthracotic lymph nodes.

Representative sections are submitted as follows: A1- vascular resection margin; A2-A3- entire staple line resection margin en face; A4-A5- entire mass with overlying pleura and adjacent uninvolved parenchyma; A6- uninvolved lung parenchyma; A7- peribronchial lymph nodes.

FROZEN SECTION DIAGNOSIS:

FSA. Lung, left upper lobe, lobectomy:
- BRONCHIAL MARGIN NEGATIVE FOR MALIGNANCY

B. The specimen consists of a 1.6 x 1.0 x 0.8 cm, tan-pink to yellow, rubbery lymph node that is serially sectioned to reveal a tan-pink to black, unremarkable cut surface. The lymph node is submitted in its entirety in cassette B.

C. The specimen consists of a 0.5 x 0.5 x 0.5 cm, tan-yellow to black, rubbery soft tissue which is submitted in total in cassette C.

D. The specimen consists of a 0.8 x 0.8 x 0.4 cm, tan-brown to black, rubbery soft tissue which is submitted in total in cassette D.

E. The specimen consists of two, tan-pink to black, rubbery lymph nodes averaging 1.2 x 0.6 x 0.4 cm. The lymph nodes are submitted in their entirety in cassette E.

F. The specimen consists of a 1.3 x 1.0 x 0.8 cm aggregate of tan-brown, rubbery soft tissue which is submitted in total in cassette F.

G. The specimen consists of a 0.6 x 0.4 x 0.4 cm, tan-brown to black, rubbery lymph node that is bisected to reveal a dark black anthracotic cut surface. The lymph node is submitted in its entirety in cassette G.

H. The specimen consists of a 2.3 x 2.0 x 0.8 cm aggregate of tan-pink to black, rubbery anthracotic lymph nodes which are submitted in total in cassettes H1 and H2.

I. The specimen consists of a 2.6 x 2.0 x 0.8 cm aggregate of tan-pink to black, rubbery anthracotic lymph nodes. The largest lymph node is bisected to reveal a dark black anthracotic cut surface. Lymph nodes are submitted in their entirety as follows: I1- multiple whole lymph nodes; I2- one bisected lymph node. ()

ICB-0-3
adenocarcinoma, NOS 8/10/13
Site: lung, upper lobe C34.1

10/1/12

[page 2 of 4]
MICROSCOPIC EXAM
DIAGNOSIS:

- A. Lung, left upper lobe, lobectomy:
- INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA

SYNOPTIC REPORT (INCLUDING SPECIMENS A-I):

SPECIMEN

- Lung
- Lobe of lung: Left upper

PROCEDURE

- Lobectomy

SPECIMEN INTEGRITY

- Intact

SPECIMEN LATERALITY

- Left

TUMOR SITE

- Upper lobe

TUMOR SIZE

- Greatest dimension: 1.6 cm

TUMOR FOCALITY

- Unifocal

HISTOLOGIC TYPE

- Adenocarcinoma

HISTOLOGIC GRADE

- G3: Poorly differentiated (high grade)

VISCERAL PLEURA INVASION

- Not identified

TUMOR EXTENSION

- Not identified

MARGINS

- BRONCHIAL MARGIN
Uninvolved by invasive carcinoma
- VASCULAR MARGIN
Uninvolved by invasive carcinoma
- PARENCHYMAL MARGIN
Not applicable
- PARIETAL PLEURAL MARGIN
Not applicable
- CHEST WALL MARGIN
Not applicable
- OTHER ATTACHED TISSUE MARGIN
Not applicable
- Distance of invasive carcinoma from closest margin: 3.6 cm
Specify margin: vascular margin

TREATMENT EFFECT

- Not applicable

LYMPH-VASCULAR INVASION

- Not identified

PERINEURAL INVASION

- Not identified

PATHOLOGIC STAGING (PTNM)

- Primary Tumor (pT)
pT1a
- Regional Lymph Nodes (pN)
pN0 (including specimens A-I)
Number examined: 31
Number involved: 0
- Distant Metastasis (pM)
Not applicable

ADDITIONAL PATHOLOGIC FINDINGS:

- Non-neoplastic lung with interstitial fibrosis
- Lymph node with granuloma

- B. Lymph nodes, station AP window, excision:
- 4 LYMPH NODES, NEGATIVE FOR MALIGNANCY

- C. lymph node, station 9, excision:
- 1 LYMPH NODE, NEGATIVE FOR MALIGNANCY

[page 3 of 4]
- GRANULOMA SEEN
- D. Lymph node, station 8, excision:
- 1 LYMPH NODE, NEGATIVE FOR MALIGNANCY
- GRANULOMA SEEN
- E. Lymph nodes, station 7, excision:
- 5 LYMPH NODES, NEGATIVE FOR MALIGNANCY
- F. Lymph nodes, station 6, excision:
- 4 LYMPH NODES, NEGATIVE FOR MALIGNANCY
- GRANULOMA SEEN
- G. Lymph node, station 10, excision:
- 1 LYMPH NODE, NEGATIVE FOR MALIGNANCY
- GRANULOMA SEEN
- H. Lymph nodes, station 11, excision:
- 6 LYMPH NODES, NEGATIVE FOR MALIGNANCY
- GRANULOMA SEEN
- I. Lymph nodes, station 12, excision:
- 6 LYMPH NODES, NEGATIVE FOR MALIGNANCY
- CALCIFIED NODULE AND GRANULOMA SEEN

COMMENT: Immunostains show that the tumor cells are positive for CK7, TTF-1, focally positive for P63 and negative for CK20. These findings are consistent with adenocarcinoma.

The AFB and GMS stains are negative for mycobacteria or fungal organisms on representative lymph node with granuloma (A7).

concur with the malignancy diagnosis in this case.

Immunostain for ALK and molecular studies for EGFR and ALK gene will be performed. The results will be issued as an addendum report after completion.

"This test was developed and its performance characteristics determined by t

It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This Laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing."

SUPPLEMENTARY REPORT(S):

*** SUPPLEMENTARY REPORT HAS BEEN ADDED/MODIFIED ***

ADDENDUM REPORT:

The addendum report is issued to give immunostain and molecular study
1

Immunostaining for ALK protein is negative in the tumor cells.

There are rare nests of monotonous epithelial cells present on a section of staple line margin after removal of staples (A2). These cells are positive for chromogranin and synaptophysin by immunostaining, consistent with small "tumorlet", microscopic. Dr.

[page 4 of 4]
*** SUPPLEMENTARY REPORT HAS BEEN ADDED/MODIFIED ***

ADDENDUM REPORT:

Molecular studies in left upper lung tumor is performed at

MOLECULAR ANALYSIS REPORT:

TEST PERFORMED: EGFR Paraffin PCR, Lung Cancer

SPECIMEN TYPE: Slides, Lung, Left Upper lobe

RESULT: No mutations were detected within the analyzed
region of the EGFR gene.

FLUORESCENCE IN SITU HYBRIDIZATION ANALYSIS REPORT:

FISH ALK FISH SPECIMEN TYPE: Slides FISH
Result: NEGATIVE: NO ALK GENE REARRANGEMENT

Interpretation: NO ALK GENE REARRANGEMENT; ADDITIONAL COPIES OF INTACT
ALK GENE HYBRIDIZATION SIGNALS
nuc ish 2p23(ALKx3~5)[13/50]

9/19/12

Source: NCI Genomic Data Commons file 67962142-847d-45a1-86cc-dc7e56f24014 (TCGA-MN-A4N5.3F2359D8-9958-485B-B00F-BD8ADD34FB1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).